Somatic mutation profile of tumor specimen TCGA-2Y-A9GU-01A (aliquot TCGA-2Y-A9GU-01A-11D-A382-10) from TCGA case TCGA-2Y-A9GU, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 55.3 years (20,187 days).
Specimen TCGA-2Y-A9GU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe8d5320-7e6c-4806-a5a8-7e524f42b078.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9GU-10A (Blood Derived Normal), aliquot TCGA-2Y-A9GU-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e03d376-3911-46a5-9ef3-e97793e4bd19

The open-access MAF lists 164 somatic variants for this specimen: 121 protein-altering or splice-affecting, 37 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 37, Nonsense Mutation 6, Splice Site 4, Frame Shift Ins 4, RNA 3, Frame Shift Del 3, Intron 2, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.464T>C p.M155T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.396); catalogued as COSV100751131; called by muse, mutect2
- ABCC5 | c.4145T>C p.L1382P | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99657553; called by muse, mutect2, varscan2
- ACAP2 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as rs761386232, COSV100462701; called by muse, mutect2, varscan2
- ACSS1 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs113598729, COSV100054054; called by muse, mutect2, varscan2
- ACTL9 | c.1165T>A p.S389T | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100185543; called by muse, mutect2, varscan2
- ACTRT2 | c.605A>C p.H202P | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101007666; called by muse, mutect2, varscan2
- ADCK1 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99452613; called by muse, mutect2, varscan2
- ADGRE1 | c.1954T>C p.F652L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99165827; called by muse, mutect2, varscan2
- AJAP1 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as COSV100982020; called by muse, mutect2, varscan2
- AKAP6 | c.2368G>T p.E790* | Nonsense Mutation (SNP) | VAF 25/140 reads (18%) | catalogued as COSV99804273; called by muse, mutect2, varscan2
- ANK2 | c.6541G>C p.D2181H | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV100004125, COSV100004572; called by muse, mutect2, varscan2
- ANKRA2 | c.290C>G p.A97G | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV99707127; called by muse, mutect2, varscan2
- APMAP | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as COSV54173581; called by muse, mutect2, varscan2
- ARHGAP21 | c.2963C>G p.P988R | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100256638; called by muse, mutect2, varscan2
- ARHGAP36 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs182540216, COSV52264298; called by muse, mutect2, varscan2
- ATP4A | c.2833G>A p.V945I | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV99383060; called by muse, mutect2, varscan2
- BAP1 | c.605G>T p.W202L | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99964463; called by muse, mutect2, varscan2
- BEND5 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs201098567; called by muse, mutect2, varscan2
- CABP5 | c.497A>T p.E166V | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99506706; called by muse, mutect2, varscan2
- CARD6 | c.1921G>C p.V641L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV99621282; called by muse, mutect2, varscan2
- CAVIN4 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs937130678, COSV100293397; called by muse, mutect2, varscan2
- CCDC189 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100079824; called by muse, mutect2, varscan2
- CCDC27 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV99622886; called by muse, mutect2, varscan2
- CCN6 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as rs782804251, COSV100037190; called by muse, mutect2, varscan2
- CFAP299 | c.63A>C p.E21D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV100812488; called by muse, mutect2, varscan2
- CHRNA7 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs532485785, COSV100181734; called by mutect2, varscan2
- CIB3 | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99521916; called by muse, mutect2, varscan2
- COL24A1 | c.691T>C p.S231P | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV100993962; called by muse, mutect2, varscan2
- CRISP2 | c.270C>G p.T90= | Splice Region (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100189229; called by muse, mutect2, varscan2
- CUL4B | c.1945T>C p.F649L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV100341152; called by muse, mutect2, varscan2
- CYSLTR1 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 160/423 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV100964753; called by muse, mutect2, varscan2
- DCAF6 | c.2028-1G>C p.X676_splice (on ENST00000312263 / NM_001349778.1; = p.X696_splice on NM_018442.3 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 34/279 reads (12%) | catalogued as COSV100394822; called by muse, varscan2
- DHX9 | c.2648T>C p.I883T | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100841517; called by muse, mutect2, varscan2
- DOP1B | c.2935G>C p.A979P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101215819; called by muse, mutect2, varscan2
- DPY19L1 | c.1545A>C p.Q515H | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV100205003; called by muse, mutect2, varscan2
- EBF1 | c.1280C>G p.T427S | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV100566556; called by muse, mutect2, varscan2
- EFL1 | c.1411A>C p.I471L | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99188552; called by muse, mutect2, varscan2
- ELFN2 | c.2212A>T p.K738* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | catalogued as COSV101297638; called by muse, mutect2
- EML2 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs750037044, COSV55598874; called by muse, mutect2, varscan2
- FAM83D | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54157186; called by muse, mutect2, varscan2
- FLG2 | c.5389G>T p.G1797* | Nonsense Mutation (SNP) | VAF 12/141 reads (9%) | catalogued as COSV101166209; called by muse, mutect2
- FLNB | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs760976111, COSV99914744; called by muse, mutect2, varscan2
- FNDC1 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs762244107, COSV99796765; called by muse, mutect2, varscan2
- GART | c.2051G>T p.G684V | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101111436; called by muse, mutect2, varscan2
- GLUD2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 83/719 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as COSV100047089; called by muse, mutect2, varscan2
- GPR174 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV52134773, COSV99034805; called by muse, mutect2, varscan2
- GRIP1 | c.1573A>T p.M525L (on ENST00000359742 / NM_001379345.1; = p.M473L on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99670936; called by muse, mutect2
- GRIP2 | c.2899T>C p.W967R (on ENST00000619221; = p.W870R on NM_001080423.4) | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99817638; called by muse, mutect2, varscan2
- HLA-B | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs281864590, COSV101318239; called by muse, mutect2, varscan2
- IBTK | c.3045G>C p.K1015N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100091464; called by muse, mutect2, varscan2
- IL31RA | c.34G>C p.A12P | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV99763551; called by muse, mutect2, varscan2
- IPCEF1 | c.1118T>C p.L373P | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99500462; called by muse, mutect2, varscan2
- ITIH2 | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100623240, COSV64435503; called by muse, mutect2, varscan2
- JADE2 | c.83C>A p.S28* | Nonsense Mutation (SNP) | VAF 9/115 reads (8%) | catalogued as COSV50915473, COSV99253613; called by muse, mutect2
- KAZN | c.2291T>A p.L764Q | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1180929668, COSV100184547; called by muse, mutect2, varscan2
- KIAA1109 | c.1436G>T p.C479F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV99175029; called by muse, mutect2, varscan2
- KIAA1109 | c.4911A>T p.L1637F | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV99175041; called by muse, mutect2, varscan2
- KIF15 | c.3862A>T p.T1288S | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100393226; called by muse, mutect2
- KRT2 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779911777, COSV100548645; called by muse, mutect2, varscan2
- LIMK1 | c.1289G>C p.S430T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100283459; called by muse, mutect2, varscan2
- LPCAT3 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs781890054, COSV99781300; called by muse, mutect2, varscan2
- LRRC7 | c.4381C>T p.R1461W (on ENST00000651989 / NM_001370785.2; = p.R1381W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs199872098, COSV99229614; called by muse, mutect2, varscan2
- LRRIQ1 | c.1470dup p.R491Tfs*14 | Frame Shift Ins (INS) | VAF 102/246 reads (41%) | catalogued as rs779699744; called by mutect2, varscan2
- MALSU1 | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as rs753431892, COSV99325822; called by muse, mutect2, varscan2
- MKNK2 | c.1354A>G p.S452G | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.164); catalogued as rs371172997; called by muse, mutect2, varscan2
- MLXIPL | c.269T>C p.F90S | Missense Mutation (SNP) | VAF 108/182 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100515545; called by muse, mutect2, varscan2
- MMP3 | c.351-1G>T p.X117_splice | Splice Site (SNP) | VAF 26/93 reads (28%) | catalogued as COSV55406495, COSV55408560; called by muse, mutect2, varscan2
- MUC4 | c.13044C>G p.F4348L (on ENST00000463781 / NM_018406.7; = p.F112L on NM_004532.6) | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV57803569; called by muse, mutect2
- MYO9B | c.5632G>A p.E1878K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101261923; called by muse, mutect2, varscan2
- NINJ2 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs989654292, COSV56749752, COSV56759942; called by muse, mutect2, varscan2
- OR13H1 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.609); catalogued as COSV100088400, COSV100088432; called by muse, mutect2, varscan2
- OR51L1 | c.232T>C p.S78P | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV100386488; called by muse, mutect2, varscan2
- PCM1 | c.514A>G p.K172E | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1160037374, COSV100279575; called by muse, mutect2, varscan2
- PLEKHH2 | c.2545C>T p.P849S | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99175085; called by muse, mutect2, varscan2
- POLR1G | c.1358C>G p.A453G | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as rs368905711, COSV99185396; called by muse, varscan2
- PPFIA1 | c.2419A>T p.I807F | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99558017; called by muse, mutect2, varscan2
- QRSL1 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.091); catalogued as rs530501491, COSV100945460; called by muse, mutect2, varscan2
- RASAL2 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.288); catalogued as COSV100862912; called by muse, mutect2, varscan2
- RD3 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs1230090648, COSV100879235; called by muse, mutect2, varscan2
- RECQL4 | c.1514G>C p.G505A | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1004394987, COSV99468187; called by muse, mutect2
- ROBO1 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101459280; called by muse, mutect2, varscan2
- ROBO2 | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1220003348, COSV59909672; called by muse, mutect2, varscan2
- ROBO2 | c.2364C>G p.I788M | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV100169820; called by muse, mutect2, varscan2
- SGIP1 | c.1297G>A p.G433S | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.986); catalogued as rs1557608913, COSV52780229; called by muse, mutect2, varscan2
- SGPP2 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58328040; called by muse, mutect2, varscan2
- SLC1A7 | c.432-2A>G p.X144_splice | Splice Site (SNP) | VAF 15/79 reads (19%) | catalogued as rs756665743, COSV101019761; called by muse, mutect2, varscan2
- SLC22A8 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.104); catalogued as rs1196576621, COSV100268080; called by muse, mutect2, varscan2
- SLX4 | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV99568518; called by muse, mutect2, varscan2
- SMAD6 | c.1432C>T p.R478W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976407320, COSV99994362; called by muse, mutect2, varscan2
- SORCS1 | c.3277G>A p.D1093N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV53906622, COSV99550120; called by muse, mutect2, varscan2
- SPATA46 | c.593T>A p.L198H | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100723609; called by muse, mutect2
- SRPK2 | c.154T>A p.S52T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100624338; called by muse, mutect2, varscan2
- SRXN1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.313); catalogued as rs777286381, COSV67937837; called by muse, mutect2, varscan2
- STYXL2 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.156); catalogued as COSV99609325; called by muse, mutect2, varscan2
- SVBP | c.115-2A>C p.X39_splice | Splice Site (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100997894; called by muse, mutect2, varscan2
- TAF2 | c.3470A>G p.K1157R | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.899); catalogued as COSV100978798; called by muse, mutect2
- TAS2R38 | c.351C>G p.Y117* | Nonsense Mutation (SNP) | VAF 22/97 reads (23%) | catalogued as COSV101516550; called by muse, mutect2, varscan2
- TDRD5 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99677117; called by muse, mutect2, varscan2
- TMEM132D | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); catalogued as rs1287424489, COSV70603146; called by muse, mutect2, varscan2
- TMEM177 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99733728; called by muse, mutect2, varscan2
- TNN | c.1996G>T p.V666L | Missense Mutation (SNP) | VAF 104/431 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV99512942; called by muse, mutect2, varscan2
- TRIM43 | c.440T>A p.L147* | Nonsense Mutation (SNP) | VAF 16/230 reads (7%) | catalogued as COSV99720103; called by muse, mutect2
- TRPC7 | c.863A>G p.E288G | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.094); catalogued as COSV100725989; called by muse, mutect2, varscan2
- TTC1 | c.139A>T p.R47W | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV99180663; called by muse, mutect2, varscan2
- TULP4 | c.3049G>A p.G1017S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs1355213958, COSV65578467; called by muse, mutect2, varscan2
- UACA | c.3807A>G p.I1269M | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV100537740; called by muse, mutect2, varscan2
- USP17L2 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV61556919; called by muse, mutect2, varscan2
- VASH2 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99663703; called by muse, mutect2
- VGLL1 | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV101034722; called by muse, mutect2, varscan2
- XYLT1 | c.1957C>A p.H653N | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.652); catalogued as COSV99763264; called by muse, mutect2, varscan2
- ZDHHC13 | c.470T>C p.V157A | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.932); catalogued as COSV101240067; called by muse, mutect2, varscan2
- ZNF19 | c.44C>G p.T15S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV99867696; called by muse, mutect2, varscan2
- ZNF229 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs200548188, COSV99350922; called by muse, mutect2, varscan2
- ZNF43 | c.2051G>T p.G684V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100731962; called by muse, mutect2, varscan2
- ZNF821 | c.901C>T p.R301C (on ENST00000425432 / NM_001376297.1; = p.R259C on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1446228645, COSV100546876; called by muse, mutect2
- CCDC15 | c.1872_1876del p.K625Sfs*15 | Frame Shift Del (DEL) | VAF 45/101 reads (45%) | called by mutect2, pindel, varscan2
- DNAAF4 | c.1016dup p.N339Kfs*7 | Frame Shift Ins (INS) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- HMCN1 | c.8862dup p.Y2955Ifs*3 | Frame Shift Ins (INS) | VAF 43/383 reads (11%) | called by mutect2, pindel, varscan2
- KANSL1 | c.1904dup p.C636Vfs*16 | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- MEP1B | c.737_738del p.L246Pfs*8 | Frame Shift Del (DEL) | VAF 19/124 reads (15%) | called by pindel, varscan2
- MT3 | c.101_134del p.C34Lfs*63 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- ACAA1 | c.249G>A p.L83= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as rs952749430, COSV57177044; called by muse, mutect2, varscan2
- ALK | c.1329T>C p.C443= | Silent (SNP) | VAF 21/221 reads (10%) | catalogued as COSV101202671; called by muse, mutect2
- AMHR2 | c.843G>A p.L281= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99143554; called by muse, mutect2
- C15orf39 | c.1671C>T p.G557= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV100641466; called by muse, mutect2, varscan2
- C17orf80 | c.903C>T p.T301= | Silent (SNP) | VAF 58/141 reads (41%) | catalogued as rs752674149, COSV99277697, COSV99278507; called by muse, mutect2, varscan2
- CDH22 | c.1464A>T p.R488= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100952981; called by muse, mutect2, varscan2
- CFAP251 | c.2478T>C p.T826= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV99996467; called by muse, mutect2
- CHRM2 | c.1311T>A p.P437= | Silent (SNP) | VAF 114/213 reads (54%) | catalogued as COSV100281886; called by muse, mutect2, varscan2
- DUOX1 | c.2985C>T p.P995= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as COSV100368450; called by muse, mutect2, varscan2
- ERCC8 | c.432T>G p.V144= | Silent (SNP) | VAF 10/226 reads (4%) | catalogued as COSV99410694; called by muse, mutect2
- FRMPD4 | c.3522C>T p.C1174= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs775346589, COSV101042769; called by muse, mutect2, varscan2
- HSPBP1 | c.846G>T p.R282= | Silent (SNP) | VAF 29/197 reads (15%) | catalogued as COSV99729277; called by muse, mutect2, varscan2
- ILRUN | c.180C>T p.G60= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as rs373019670; called by muse, mutect2, varscan2
- JCAD | c.2820T>C p.G940= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100948556; called by muse, mutect2, varscan2
- KHDC4 | c.1395A>G p.T465= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as COSV100850851; called by muse, mutect2, varscan2
- LPA | c.3393C>T p.C1131= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs758509383, COSV100308010; called by muse, mutect2, varscan2
- LRP1 | c.3144C>T p.H1048= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs373173236; called by muse, mutect2, varscan2
- MTUS1 | c.2083C>T p.L695= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100030001, COSV50555708; called by muse, mutect2, varscan2
- MTUS2 | c.1197C>T p.G399= | Silent (SNP) | VAF 89/187 reads (48%) | catalogued as COSV101462363; called by muse, mutect2, varscan2
- OR2W3 | c.171C>A p.T57= | Silent (SNP) | VAF 43/152 reads (28%) | catalogued as COSV100831830; called by muse, mutect2, varscan2
- PAFAH1B3 | c.412C>T p.L138= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as COSV99360253; called by muse, mutect2, varscan2
- PCDH8 | c.435C>T p.S145= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV58814818; called by muse, mutect2, varscan2
- PCDHGB6 | c.99C>A p.I33= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV99546458; called by muse, mutect2
- PLXNA2 | c.1653A>C p.R551= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV100885877; called by muse, mutect2, varscan2
- PSG6 | c.339G>A p.Q113= | Silent (SNP) | VAF 31/128 reads (24%) | catalogued as COSV99414513; called by muse, mutect2, varscan2
- PTPRT | c.1782C>T p.Y594= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs377291418; ClinVar: likely benign; called by muse, mutect2, varscan2
- RCOR3 | c.615A>G p.Q205= | Silent (SNP) | VAF 76/372 reads (20%) | catalogued as rs376624554; called by muse, mutect2, varscan2
- RNMT | c.1146A>G p.A382= | Silent (SNP) | VAF 93/569 reads (16%) | catalogued as COSV100054946; called by muse, mutect2, varscan2
- RORB | c.261A>T p.S87= (on ENST00000396204 / NM_001365023.1; = p.S76= on NM_006914.4) | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs1267153412, COSV100974551; called by muse, mutect2
- TEX9 | c.492T>A p.I164= | Silent (SNP) | VAF 57/290 reads (20%) | catalogued as COSV100771660; called by muse, mutect2, varscan2
- TMEM135 | c.1353A>T p.P451= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV100450156; called by muse, mutect2, varscan2
- TRIM72 | c.174C>T p.A58= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100265477; called by muse, mutect2, varscan2
- TRO | c.4215C>T p.G1405= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV99437287; called by muse, mutect2, varscan2
- TRPM1 | c.219C>T p.I73= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99856621; called by muse, mutect2, varscan2
- TUBGCP2 | c.2466C>T p.I822= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99428333; called by muse, mutect2, varscan2
- USP51 | c.651T>C p.R217= | Silent (SNP) | VAF 94/261 reads (36%) | catalogued as COSV101540698; called by muse, mutect2, varscan2
- ZNF431 | c.309T>C p.D103= | Silent (SNP) | VAF 73/161 reads (45%) | catalogued as COSV100219053, COSV60673809; called by muse, mutect2, varscan2
- C3orf35 | n.1491A>G | RNA (SNP) | VAF 7/47 reads (15%) | catalogued as rs774538380; called by muse, mutect2, varscan2
- DCHS2 | n.4712A>G | RNA (SNP) | VAF 62/161 reads (39%) | catalogued as COSV100602610; called by muse, mutect2, varscan2
- KIR3DX1 | n.226T>C | RNA (SNP) | VAF 45/101 reads (45%) | catalogued as COSV55597243; called by muse, mutect2, varscan2
- NACA | c.70+4196A>G | Intron (SNP) | VAF 21/97 reads (22%) | catalogued as COSV100771631; called by muse, mutect2, varscan2
- TIMMDC1 | c.-1C>A | 5'UTR (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99809836; called by muse, mutect2, varscan2
- TTN | c.10360+1935T>G | Intron (SNP) | VAF 20/98 reads (20%) | catalogued as COSV100629024; called by muse, mutect2, varscan2
